Somatic mutation profile of tumor specimen TCGA-V1-A9Z9-01A (aliquot TCGA-V1-A9Z9-01A-21D-A41K-08) from TCGA case TCGA-V1-A9Z9, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland.
Specimen TCGA-V1-A9Z9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f6eb8c9f-8a0d-425e-a1a9-bfb0f901c17f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V1-A9Z9-10A (Blood Derived Normal), aliquot TCGA-V1-A9Z9-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a5236cd6-bfc2-410b-86b3-412b5aa32d05

The open-access MAF lists 32 somatic variants for this specimen: 25 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 17, Silent 7, Frame Shift Del 5, Nonsense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 25/66 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs121913293, CM074467, COSV64288569, COSV64310838; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AKAP9 | c.6681del p.E2228Rfs*5 (on ENST00000359028; = p.E2204Rfs*5 on NM_005751.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 13/61 reads (21%) | catalogued as rs1245389532; called by mutect2, pindel, varscan2
- APBA3 | c.35G>A p.G12E | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as COSV100349583; called by muse, mutect2, varscan2
- DMD | c.7269G>C p.K2423N | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as COSV100626251; called by muse, mutect2, varscan2
- ETV3 | c.230G>A p.G77D | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100460996; called by mutect2, varscan2
- EWSR1 | c.641A>T p.Y214F | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100131036; called by muse, mutect2, varscan2
- FAM98A | c.190C>T p.Q64* | Nonsense Mutation (SNP) | VAF 21/83 reads (25%) | catalogued as rs1262954038, COSV53210252, COSV99479106; called by muse, mutect2, varscan2
- FCGBP | c.10208C>T p.A3403V | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.03); catalogued as rs779909369; called by muse, mutect2, varscan2
- ITGAL | c.3046G>A p.G1016R | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.373); catalogued as rs557551761, COSV100776117; called by muse, mutect2, varscan2
- LAIR2 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.908); catalogued as rs1360950295, COSV56623497; called by muse, mutect2, varscan2
- LILRB4 | c.638T>A p.L213Q | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.97); catalogued as COSV54408975, COSV99553560; called by muse, mutect2, varscan2
- MARK3 | c.56C>G p.T19R | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.385); catalogued as rs375599947, COSV99357732, COSV99357957; called by muse, varscan2
- MYBPC1 | c.1723A>G p.T575A (on ENST00000550270 / NM_206820.2; = p.T600A on NM_002465.4) | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100637805; called by muse, mutect2, varscan2
- MYOM1 | c.3733C>G p.P1245A | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV55302530; called by muse, mutect2, varscan2
- PCYT1B | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as COSV100996759; called by muse, mutect2, varscan2
- USP46 | c.128C>G p.T43R | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101484219; called by muse, mutect2, varscan2
- VTN | c.117G>C p.Q39H | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99879532; called by muse, mutect2, varscan2
- ZDBF2 | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.092); catalogued as COSV100984468; called by muse, mutect2, varscan2
- ZFHX4 | c.6424A>T p.K2142* | Nonsense Mutation (SNP) | VAF 5/26 reads (19%) | catalogued as COSV99256203; called by muse, mutect2, varscan2
- ARFIP2 | c.238_239del p.P80Wfs*3 | Frame Shift Del (DEL) | VAF 9/57 reads (16%) | called by mutect2, pindel, varscan2
- GAL3ST4 | c.1354dup p.E452Gfs*7 | Frame Shift Ins (INS) | VAF 15/55 reads (27%) | called by mutect2, pindel, varscan2
- LCP2 | c.1472_1473del p.G491Efs*12 | Frame Shift Del (DEL) | VAF 25/97 reads (26%) | called by mutect2, pindel, varscan2
- PAX8 | c.716del p.P239Hfs*40 | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | called by mutect2, pindel
- SETD2 | c.5361_5365del p.D1788Pfs*4 | Frame Shift Del (DEL) | VAF 16/49 reads (33%) | called by mutect2, pindel, varscan2
- SYNRG | c.3210C>A p.H1070Q | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CRYGC | c.390C>T p.C130= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as COSV52204738; called by muse, mutect2, varscan2
- LRCH4 | c.399C>T p.I133= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as rs1162036916, COSV99575068; called by muse, mutect2, varscan2
- OR8D1 | c.909G>A p.K303= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV100766627, COSV63443224; called by muse, mutect2, varscan2
- ORC5 | c.144A>G p.Q48= | Silent (SNP) | VAF 26/72 reads (36%) | catalogued as COSV99856778; called by muse, mutect2, varscan2
- PAH | c.744G>T p.L248= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as COSV100187730; called by muse, mutect2, varscan2
- PNP | c.339C>T p.V113= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs1180551873, COSV100828940; called by muse, mutect2
- SASH1 | c.1689C>T p.T563= | Silent (SNP) | VAF 31/112 reads (28%) | catalogued as rs757013020, COSV100820986; called by muse, mutect2, varscan2
